CPTAC case C3L-06217 — Skin — Nevi and Melanomas (CPTAC-3)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of the Clinical Proteomic Tumor Analysis Consortium (CPTAC). Disease type: Nevi and Melanomas; Primary site: Skin. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/a52eaa9e-0dad-460b-9c5e-aca0d8783b28

Demographics
Sex at birth: female; Race: white; Year of birth: 1976; Vital status: Alive; Country of birth: Serbia.

Diagnoses (1)
1. Malignant melanoma, NOS: ICD-O-3 morphology code: 8720/3; Tissue or organ of origin: Skin, NOS; Site of resection or biopsy: Skin, NOS; Age at diagnosis: 43.7 years (15,954 days); Year of diagnosis: 2020; AJCC staging edition: 8th; AJCC clinical M: M0; AJCC pathologic T: T3a; AJCC pathologic N: N1; AJCC pathologic stage: Stage IIIB; Residual disease: R0; Last known disease status: Tumor free; Days to last known disease status: 1,309 days (3.6 years); Progression or recurrence: no; Days to last follow up: 1,309 days (3.6 years); Clark level: IV; Tumor focality: Unifocal; Ulceration indicator: No.
   Pathology details: Breslow thickness category: >2.0-4.0 mm; Greatest tumor dimension: 0.7 cm; Lymph node involvement: Positive; Lymph nodes positive: 1; Lymph nodes tested: 6; Lymphatic invasion present: No; Margin status: Uninvolved; Perineural invasion present: No; Vascular invasion present: No.

Follow-up (3 entries)
- Days to follow up: 603 days (1.7 years); Disease response: Tumor Free; Karnofsky performance status: 90; ECOG performance status: 1.
- Days to follow up: 947 days (2.6 years); Disease response: Tumor Free; Karnofsky performance status: 90; ECOG performance status: 1.
- Days to follow up: 1,309 days (3.6 years); Disease response: Tumor Free; Karnofsky performance status: 90; ECOG performance status: 1.

Exposures
- Tobacco smoking status: Lifelong Non-Smoker; Alcohol history: No; Alcohol intensity: Lifelong Non-Drinker.

Biospecimens (2 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample C3L-06217-02: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Lymph Node; Preservation method: Snap Frozen; Freezing method: LN2; Days to sample procurement: 253 days; Initial weight: 391 mg; Method of sample procurement: Tumor Resection; Diagnosis pathologically confirmed: Yes.
  Slide C3L-06217-22: Section location: Lymph node; Percent tumor nuclei: 80; Percent necrosis: 5.
- Sample C3L-06217-31: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood Components NOS; Biospecimen anatomic site: Blood; Preservation method: Frozen; Freezing method: -20 (unit not recorded by GDC); Days to sample procurement: 253 days; Method of sample procurement: Blood Draw.
